Gene-level copy-number profile of specimen HCM-BROD-0874-C43-85N from HCMI case HCM-BROD-0874-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.5 years (21,744 days).
Specimen HCM-BROD-0874-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 15.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 34967382-93d0-4678-99be-bcb7b4ce4cbe.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0874-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,249 have no estimate.
https://portal.gdc.cancer.gov/files/9e97b98e-8c34-45c1-8890-99db465dcd65

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,634; copy number 2: 3,043; copy number 3: 21,666; copy number 4: 24,312; copy number 5: 6,716; copy number 6: 559; copy number 7: 436; copy number 8: 4; copy number 9: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,126,974–120,127,074, 1 gene, copy number 9: RNU6-465P.
- chr1:149,197,992–149,321,732, 3 genes, copy number 9 (within-gene range 2–9): AC245297.1, AC245297.2, 7SK.

Autosomal genes at a single copy (total copy number 1): 1,634. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
